Gene-level copy-number profile of tumor specimen TCGA-66-2792-01A from TCGA case TCGA-66-2792, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 58.7 years (21,428 days).
Specimen TCGA-66-2792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0a93a926-8ec2-4978-8060-374ac052ad23.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2792-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eeea15d4-b1ff-4137-b3aa-ae26e082e025

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 971; copy number 2: 25,340; copy number 3: 14,960; copy number 4: 14,324; copy number 5: 2,912; copy number 6: 392; copy number 7: 407; copy number 8: 33; copy number 9: 41; copy number 10: 9; copy number 11: 71; copy number 12: 19; copy number 13: 48; copy number 16: 100; copy number 17: 2; copy number 18: 75; copy number 19: 82; copy number 29: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2792-01A-01D-0978-01): tumor purity 0.66, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,213 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:99,337,371–99,490,035, 3 genes, copy number 6: EIF5B, REV1, AC018690.1.
- chr2:115,468,056–130,375,405, 211 genes, copy number 5–7 (broad region; genes not listed).
- chr2:132,685,224–132,816,896, 1 gene, copy number 5 (within-gene range 3–5): AC010974.2.
- chr3:93,843,764–110,727,121, 215 genes, copy number 6–7 (broad region; genes not listed).
- chr3:117,672,154–117,997,592, 1 gene, copy number 5 (within-gene range 4–5): AC092691.1.
- chr3:164,670,878–198,222,513, 636 genes, copy number 5–19 (broad region; genes not listed).
- chr5:1,798,385–45,895,970, 645 genes, copy number 5–6 (broad region; genes not listed).
- chr6:63,193,072–65,707,226, 24 genes, copy number 8–12 (within-gene range 4–12): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr7:53,002,420–57,837,046, 171 genes, copy number 11–16 (broad region; genes not listed).
- chr7:98,478,551–110,592,204, 308 genes, copy number 6–9 (broad region; genes not listed).
- chr7:120,988,697–124,489,572, 53 genes, copy number 5 (within-gene range 4–5): CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1.
- chr8:31,598,099–32,855,666, 8 genes, copy number 7 (within-gene range 4–7): RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1.
- chr8:49,740,216–52,976,116, 30 genes, copy number 10–29: PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1.
- chr9:24,905,469–24,905,735, 1 gene, copy number 5: RMRPP5.
- chr11:55,506,635–56,751,902, 98 genes, copy number 6 (broad region; genes not listed).
- chr17:33,791,838–40,721,932, 297 genes, copy number 5 (broad region; genes not listed).
- chr17:41,026,026–43,476,665, 192 genes, copy number 5 (broad region; genes not listed).
- chr18:20,946,906–28,824,826, 140 genes, copy number 5–10 (broad region; genes not listed).
- chr19:27,638,483–43,171,515, 619 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:87,250–30,214,976, 560 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
